Gene-level copy-number profile of tumor specimen TCGA-VD-AA8S-01B from TCGA case TCGA-VD-AA8S, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIA; Age at diagnosis: 40.2 years (14,681 days).
Specimen TCGA-VD-AA8S-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UVM.037f91d6-c581-47b7-8fbd-4979082ec4be.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VD-AA8S-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fe762e27-884d-4956-b0a9-996d5a167f49

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,380; copy number 2: 43,140; copy number 3: 12,046; copy number 4: 2,067; copy number 7: 22; copy number 8: 165.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VD-AA8S-01B-11D-A39V-01): tumor purity 0.93, ploidy 2.31, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 187 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:4,702,463–5,054,423, 8 genes, copy number 7: PSMC1P11, CDYL, AL356747.1, CDYL-AS1, AL359643.1, RPP40, LYRM4-AS1, AL359643.2.
- chr6:5,261,044–5,829,192, 1 gene, copy number 7 (within-gene range 4–7): FARS2.
- chr6:5,451,683–5,918,844, 7 genes, copy number 7: AL021328.1, HNRNPA1P37, AL022097.1, AL136968.2, AL136968.1, AL136307.1, RN7SL221P.
- chr6:6,794,915–7,881,728, 24 genes, copy number 8 (within-gene range 4–8): BTF3P7, AL158817.1, RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA, AL589644.1, AL139095.5, SSR1, AL139095.4, CAGE1, AL139095.1, AL139095.2, AL139095.3, RIOK1, HNRNPLP1, AL138878.1, AL138878.2, AL031058.1, DSP, SNRNP48, AL390026.1, BMP6.
- chr6:8,158,162–16,295,549, 122 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr6:16,761,138–17,737,556, 19 genes, copy number 8: ATXN1-AS1, AL137003.1, AL133405.2, AL133405.1, AL138740.1, STMND1, AL136305.1, RBM24, AL034372.1, CAP2, RPL7P26, SUMO2P13, AL138824.1, FAM8A1, NUP153, RNU6-190P, AL138724.1, RNA5SP204, Y_RNA.
- chr6:18,223,860–18,368,644, 6 genes, copy number 7: DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
